CCDI case PBCWMB — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS.
https://portal.gdc.cancer.gov/cases/257535d9-9116-4e36-b558-ad9af298fd15

Demographics
Sex at birth: female.

Biospecimens (3 samples)
- Sample 0E1SXY: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0E1SY2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0E1SYK: Tissue type: Tumor; Specimen type: Solid Tissue.
